CPTAC case C3L-06017 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8dd5d158-9030-407f-ab42-620b522542ee

Demographics
Sex at birth: male; Race: white; Year of birth: 1947; Vital status: Dead; Days to death: 228 days; Year of death: 2020; Cause of death: Cancer Related; Country of birth: Bulgaria.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 72.2 years (26,380 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 228 days; Progression or recurrence: yes; Days to last follow up: 52 days; Tumor focality: Multifocal; Ulceration indicator: No.
   Pathology details: Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 5; Margin status: Indeterminate.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (1 entry)
- Days to follow up: 52 days; Disease response: With Tumor; ECOG performance status: 0.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 98; Cigarettes per day: 40; Tobacco smoking onset year: 1970; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 52.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06017-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -4 days; Initial weight: 367 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-06017-21: Section location: Extremities; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-06017-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -3 days; Method of sample procurement: Blood Draw.
